Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABI, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABI-01A (Primary Tumor).

[page 1 of 4]
Surgery date: Surgical Pathology
REVISED REPORT (Revised information underlined)

ICD-O-3
Adenocarcinoma NOS
8140/3
Site Pancreas head
C25.0
JAS 5/5/14

DIAGNOSIS:

- A. Lymph nodes, duodenal colic, biopsy: Fibroadipose tissue, negative for tumor.
- B. Lymph node, common hepatic artery, biopsy: A single (1) lymph node is negative for tumor.
- C. Soft tissue, pancreatic neck margin, biopsy: Negative for tumor
- D. Soft tissue, common hepatic duct margin, biopsy: Negative for tumor.
- E. Head of pancreas, duodenum, common bile duct, and gallbladder; Whipple resection: Poorly differentiated adenocarcinoma, forming a 3.5 x 3.0 x 2.5 cm mass within the head of the pancreas. Tumor extends beyond pancreas and involves peripancreatic soft tissue. Perineural invasion is identified. Angiolymphatic invasion is not identified. Multiple (17 peripancreatic, 1 periduodenal) lymph nodes are negative for tumor. Gallbladder without diagnostic abnormality. The uncinate margin contains a microscopic focus of tumor. The portal vein groove is negative for tumor.

With available surgical material, [AJCC pT3N0] (7th edition, 2010).

Seen in consultation with

AMENDMENTS: (Previous Signout Date:

Revision Description: Uncinate and portal vein groove margin omitted from part E.

....Original Diagnosis....

- A. Lymph nodes, duodenal colic, biopsy: Fibroadipose tissue, negative for tumor.
- B. Lymph node, common hepatic artery, biopsy: A single (1) lymph node is negative for tumor.
- C. Soft tissue, pancreatic neck margin, biopsy: Negative for tumor
- D. Soft tissue, common hepatic duct margin, biopsy: Negative for tumor.
- E. Head of pancreas, duodenum, common bile duct, and gallbladder; Whipple resection: Poorly differentiated adenocarcinoma, forming a

[page 2 of 4]
3.5 x 3.0 x 2.5 cm mass within the head of the pancreas. Tumor extends beyond pancreas and involves peripancreatic soft tissue. Perineural invasion is identified. Angiolymphatic invasion is not identified. Multiple (17 peripancreatic, 1 periduodenal) lymph nodes are negative for tumor. Gallbladder without diagnostic abnormality.

With available surgical material, [AJCC pT3N0] (7th edition, 2010).

Seen in consultation with

Signing Pathologist

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Lymph nodes, duodenal colic, biopsy: Fibroadipose tissue, negative for tumor.

B. Lymph node, common hepatic artery, biopsy: A single (1) lymph node is negative for tumor.

C. Soft tissue, pancreatic neck margin, biopsy: Duct margins are negative for dysplasia with mucinous change.

D. Soft tissue, common hepatic duct margin, biopsy: Negative for tumor.

E. Head of pancreas, duodenum, common bile duct, and gallbladder; Whipple resection: Invasive carcinoma, involving the head of the pancreas.

Frozen section histologic interpretation of duodenal colic lymph nodes and common hepatic artery lymph nodes performed by:

Frozen section histologic interpretation pancreatic neck margin performed by:

Frozen section histologic interpretation of common hepatic duct margin, head of pancreas, duodenum, common bile duct, and gallbladder performed by:

GROSS DESCRIPTION:

A. Received fresh labeled "duodenal colic lymph nodes" is a 4.0 x 3.0 x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted. Grossed by

B. Received fresh labeled "common hepatic artery lymph nodes" is a 2.2 x 2.0 x 0.8 cm aggregate of adipose and lymphatic tissue. Lymph

[page 3 of 4]
nodes submitted. Grossed by

C. Received fresh labeled "pancreatic neck margin" is a 3.0 x 1.5 x 1.0 cm fragment of pancreas without orientation. Margin submitted. Grossed by

D. Received fresh labeled "common hepatic duct margin" is a 0.9 x 0.3 x 0.3 cm portion of duct without orientation. Margin submitted. Grossed by

E. Received fresh labeled "head of pancreas, duodenum, portion of jejunum, gallbladder" is a Whipple specimen consisting of 29.0 cm in length portion of duodenum, 6.0 x 4.5 x 4.3 cm portion of pancreas, and 10.5 x 4.0 x 1.5 cm gallbladder. The pancreatic uncinate margin is inked yellow and shaved. The portal vein groove is inked black and submitted perpendicularly. There is a 3.5 x 3.0 x 2.5 cm diffusely infiltrative mass within the head at the uncinate margin. The mass is confined to the pancreas. The gallbladder contains no choleliths. Peripancreatic lymph nodes and periduodenal lymph nodes are identified. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Duodenal colic lymph nodes

- 1 Duodenal colic LNs 4 (A1)
- 2 Duodenal colic LNs 3 (A2)

Part B: Common hepatic artery lymph nodes

- 1 Com hepatic artery LN2(B1)

Part C: Pancreatic neck margin

- 1 Pancreatic neck margin 1
- 2 Pancreatic neck margin 2

Part D: Common hepatic duct margin

- 1 Common hepatic duct margin

Part E: Head of pancreas, duodenum, portion of jejunum, gallbladder

- 1 Uncinate margin 1 top
- 2 Uncinate margin 1 bottom
- 3 Uncinate margin 2
- 4 Portal vein groove margin
- 5 Tumor 1
- 6 Ampulla
- 7 Pancreatic duct
- 8 Tumor with bile duct
- 9 Peripancreatic LN 5 (E1)
- 10 Peripancreatic LN 1 (E2)
- 11 Peripancreatic LN 4 (E3)
- 12 Peripancreatic LN 3 (E4)

[page 4 of 4]
- 13 Peripancreatic LN 1 (E5)
- 14 Peripancreatic LN 4 (E6)
- 15 Peripancreatic LN 5 (E7)
- 16 Periduodenal LN 1 (E8)
- 17 Gallbladder 1
- 18 Gallbladder 2

Source: NCI Genomic Data Commons file 96d69f34-ab34-4573-9968-dd1dcc14b375 (TCGA-2J-AABI.F0521573-7B87-4E0E-AA23-4B49466E8BAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).